Somatic mutation profile of tumor specimen TCGA-LN-A4A2-01A (aliquot TCGA-LN-A4A2-01A-31D-A27G-09) from TCGA case TCGA-LN-A4A2, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 57.8 years (21,122 days).
Specimen TCGA-LN-A4A2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e742d646-eb44-4c74-ac0c-8dba2277a109.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A4A2-10A (Blood Derived Normal), aliquot TCGA-LN-A4A2-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e172a2a1-bf57-4e9f-b782-18d0e5785fea

The open-access MAF lists 155 somatic variants for this specimen: 112 protein-altering or splice-affecting, 35 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 35, Nonsense Mutation 7, Intron 4, In Frame Del 3, Frame Shift Del 2, Splice Site 2, RNA 2, 3'UTR 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 78/358 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.376-2A>T p.X126_splice | Splice Site (SNP) | VAF 92/216 reads (43%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic / not provided; called by muse, varscan2
- AGAP4 | c.988A>G p.T330A | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs559818160; called by muse, mutect2, varscan2
- AKR1A1 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as COSV61087134; called by muse, mutect2, varscan2
- ATG3 | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV51928759; called by muse, mutect2, varscan2
- BRCA2 | c.9187C>T p.P3063S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs80359176; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CDH10 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52591639; called by muse, mutect2, varscan2
- CIAO1 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51497731; called by muse, mutect2, varscan2
- COL11A1 | c.4532del p.P1511Qfs*76 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | catalogued as COSV62173335; called by mutect2, pindel
- CREB3L4 | c.658_660del p.K220del | In Frame Del (DEL) | VAF 5/46 reads (11%) | catalogued as rs778091329; called by pindel, varscan2
- CYB5RL | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs780876546, COSV55279599, COSV99838827; called by muse, mutect2, varscan2
- DMXL1 | c.8611C>T p.L2871F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288088180, COSV60715560; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2599G>A p.G867S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs192602550; called by muse, mutect2, varscan2
- ERICH3 | c.3206C>G p.S1069C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV104399526; called by muse, mutect2, varscan2
- ERN2 | c.1900G>A p.V634M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868797379; called by muse, mutect2, varscan2
- ESYT3 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as rs1360164806; called by muse, mutect2, varscan2
- IQUB | c.2054C>G p.S685* | Nonsense Mutation (SNP) | VAF 6/73 reads (8%) | catalogued as COSV61237348; called by muse, mutect2
- KANK1 | c.1955C>G p.T652S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV63211382; called by muse, mutect2, varscan2
- KEAP1 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260458, COSV50275012, COSV50315065; called by muse, mutect2
- KLHDC2 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1478535502; called by muse, mutect2, varscan2
- KLHL22 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747088998, COSV61021225; called by muse, mutect2
- KMT2E | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.25); catalogued as rs969860024; called by muse, mutect2, varscan2
- LCT | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51555635; called by muse, mutect2, varscan2
- LGSN | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs745357482, COSV65728474; called by muse, mutect2, varscan2
- LRRC66 | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs1484480125; called by muse, mutect2, varscan2
- MAGEC3 | c.1892C>A p.A631E | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV53579043; called by muse, mutect2, varscan2
- MAP1LC3C | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs776473823, COSV61803920; called by muse, mutect2, varscan2
- MGAM | c.2413G>C p.E805Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV72073550; called by muse, mutect2, varscan2
- MTMR4 | c.3329G>A p.R1110H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369998064, COSV60200863; called by muse, mutect2, varscan2
- MUC16 | c.14269C>T p.P4757S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs752575324; called by muse, mutect2, varscan2
- MYH1 | c.2514C>A p.F838L | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV56858994; called by muse, mutect2, varscan2
- NPTX2 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55717664; called by muse, mutect2, varscan2
- OAS2 | c.1082G>C p.C361S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60804748; called by muse, mutect2, varscan2
- OBSCN | c.3775G>T p.A1259S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.119); catalogued as COSV52785861; called by muse, mutect2, varscan2
- OMA1 | c.1142A>G p.Y381C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV62256212; called by muse, mutect2, varscan2
- OR52L1 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs769350807, COSV59988162; called by muse, mutect2, varscan2
- OR5B3 | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.042); catalogued as rs77702214; called by muse, mutect2
- PLCB1 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV62046277; called by muse, mutect2, varscan2
- PRG3 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs779423526, COSV54663411; called by muse, mutect2, varscan2
- REG3A | c.470G>T p.R157M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100532478; called by muse, mutect2, varscan2
- RELN | c.8485G>T p.G2829* | Nonsense Mutation (SNP) | VAF 28/121 reads (23%) | catalogued as COSV100632277; called by muse, mutect2, varscan2
- RINT1 | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777291719, COSV57560745; called by muse, mutect2, varscan2
- SERPINH1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs995079770; called by muse, mutect2, varscan2
- SIPA1L2 | c.3790G>A p.D1264N | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs532670311, COSV53393284; called by muse, mutect2, varscan2
- SLC44A1 | c.1254-1G>C p.X418_splice | Splice Site (SNP) | VAF 33/90 reads (37%) | catalogued as COSV100570542; called by muse, mutect2, varscan2
- SYT14 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.168); catalogued as rs796524658, COSV99655818; called by muse, mutect2, varscan2
- TNN | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as rs762192072; called by muse, mutect2, varscan2
- TRIP10 | c.1789C>T p.R597* (on ENST00000313244 / NM_001288962.2; = p.R541* on NM_004240.4) | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs1200214402; called by muse, mutect2, varscan2
- TSPEAR | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs146216896, COSV100554923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSPYL1 | c.479G>T p.C160F | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.36); catalogued as rs745917630; called by muse, mutect2, varscan2
- TTN | c.31736C>T p.A10579V (on ENST00000591111; = p.A9652V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | PolyPhen benign (0.003); catalogued as COSV59936707; called by muse, mutect2
- USP14 | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1167545631; called by muse, mutect2, varscan2
- WDR43 | c.1243A>G p.I415V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs780225617; called by muse, mutect2, varscan2
- WHRN | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as rs1378146164; called by muse, mutect2, varscan2
- ZNF578 | c.632A>T p.N211I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as rs763785937, COSV69736207; called by muse, mutect2, varscan2
- ZNF655 | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV53158923; called by muse, mutect2, varscan2
- ADIPOR1 | c.650T>C p.M217T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.349); called by muse, mutect2
- ANKRD50 | c.136A>G p.S46G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASXL3 | c.2278A>T p.I760L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2
- BPTF | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPNS1 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CLTC | c.1620A>T p.E540D | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- COL7A1 | c.5197_5211del p.K1733_G1737del | In Frame Del (DEL) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- COPS5 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CPAMD8 | c.656G>T p.G219V (on ENST00000651564; = p.G172V on NM_015692.5) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CPS1 | c.4391T>C p.L1464P | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- DDOST | c.218A>T p.E73V (on ENST00000415136; = p.E56V on NM_005216.5) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DMD | c.2711C>A p.P904H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EIF3E | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ELMO2 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLG | c.6016G>A p.G2006R | Missense Mutation (SNP) | VAF 50/556 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2
- GLB1 | c.1279A>C p.S427R | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GPR89A | c.903T>G p.I301M | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H4C13 | c.180A>T p.K60N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- H4C13 | c.179A>G p.K60R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- IDH3B | c.623A>G p.K208R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- INO80D | c.2737C>G p.L913V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITGB4 | c.1530_1538del p.K510_S513delinsN | In Frame Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- KIAA0319L | c.56A>G p.Y19C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL14 | c.1505A>G p.Q502R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KRT8 | c.1225A>T p.M409L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LAMB2 | c.1539C>A p.S513R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MAST4 | c.3482A>G p.Y1161C (on ENST00000403625 / NM_001164664.2; = p.Y972C on NM_015183.3) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- MNDA | c.950C>A p.S317Y | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYADM | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NCOA4 | c.954G>C p.E318D | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- NME8 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OAT | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- OR7D4 | c.829A>C p.M277L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PCDH19 | c.1917G>T p.E639D | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.741); called by muse, varscan2
- PKDREJ | c.6579G>A p.M2193I | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLCG1 | c.2897_2898insG p.D966Efs*2 | Frame Shift Ins (INS) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.2235_2244del p.Y745* | Frame Shift Del (DEL) | VAF 46/96 reads (48%) | called by mutect2, pindel, varscan2
- PRDM9 | c.2206C>A p.L736I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB10 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- RECQL | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); called by muse, varscan2
- RP1 | c.3949C>G p.Q1317E | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIN3A | c.1773G>T p.W591C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX29 | c.1258A>G p.S420G | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPATA31A3 | c.3501C>G p.I1167M | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SPOCK3 | c.1175G>C p.S392T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- STK10 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLE2 | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- TMC1 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TMEFF2 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 24/133 reads (18%) | called by muse, mutect2, varscan2
- TRAIP | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.031); called by muse, mutect2
- TSPAN33 | c.283C>A p.Q95K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VCL | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR76 | c.1801A>C p.M601L | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- WRN | c.2717G>C p.S906T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- XIRP2 | c.2725A>G p.R909G (on ENST00000628543; = p.R1084G on NM_152381.6) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- ZNF749 | c.506A>G p.Q169R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- AHNAK2 | c.17013A>G p.R5671= | Silent (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.108C>T p.C36= | Silent (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- ATP8B3 | c.369G>A p.K123= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- CCDC142 | c.2142G>A p.P714= (on ENST00000393965 / NM_001365575.2; = p.P707= on NM_032779.4) | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs768231556, COSV50688752; called by muse, mutect2, varscan2
- CCDC151 | c.693G>T p.L231= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- CD300LG | c.231C>A p.G77= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- CDHR5 | c.2439C>T p.S813= (on ENST00000358353 / NM_001171968.2; = p.S819= on NM_021924.5) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs764911557; called by muse, mutect2, varscan2
- DMD | c.2712C>T p.P904= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs1267801118; called by muse, mutect2, varscan2
- EIF3J | c.330A>G p.P110= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV56008465; called by muse, mutect2, varscan2
- EML5 | c.3771C>T p.G1257= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs1024660402, COSV61347905; called by muse, mutect2, varscan2
- FMN2 | c.2724G>T p.L908= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- FOXR2 | c.312G>C p.L104= | Silent (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- GLP2R | c.711C>T p.N237= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV52325142; called by muse, mutect2, varscan2
- KCNQ3 | c.273C>G p.T91= | Silent (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- KLF1 | c.969G>A p.S323= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs780786728; called by muse, mutect2, varscan2
- KLF7 | c.588T>C p.S196= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- MAPK3 | c.672G>A p.K224= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs763165244; called by muse, mutect2, varscan2
- MASP2 | c.447G>A p.A149= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs1181755451; called by muse, mutect2, varscan2
- MDN1 | c.3489G>A p.A1163= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs764850569, COSV65521476; called by muse, mutect2, varscan2
- MYO7B | c.3258C>T p.P1086= | Silent (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- NCK1 | c.330C>T p.P110= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as rs548833073; called by muse, mutect2, varscan2
- NDUFA8 | c.186G>T p.L62= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- OLFM3 | c.81A>T p.P27= | Silent (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- OR4A16 | c.207C>A p.A69= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- OR4K14 | c.843A>G p.P281= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- PLOD1 | c.114C>T p.T38= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs11553679, COSV99538997; ClinVar: likely benign; called by muse, mutect2, varscan2
- PMS1 | c.2463A>G p.K821= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs1465085668; called by muse, mutect2, varscan2
- RAPGEF1 | c.1434C>T p.Y478= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs368148839, COSV100940685; called by muse, mutect2, varscan2
- SLC11A1 | c.1575C>A p.T525= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- SNAP47 | c.444G>C p.L148= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV100248290; called by muse, mutect2
- TAS2R16 | c.402G>C p.L134= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- TTN | c.27018C>A p.A9006= (on ENST00000591111; = p.A8079= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- VIRMA | c.357T>C p.C119= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs771028941; called by muse, mutect2, varscan2
- VNN2 | c.1098C>T p.C366= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs977332042, COSV58472932; called by muse, mutect2, varscan2
- ZNF646 | c.4224G>A p.A1408= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs369374909; called by muse, mutect2, varscan2
- CLLU1 | n.1065C>A | RNA (SNP) | VAF 7/48 reads (15%) | catalogued as COSV101029224; called by muse, mutect2, varscan2
- COG5 | c.1686+1491C>T | Intron (SNP) | VAF 7/45 reads (16%) | catalogued as COSV51754239; called by muse, mutect2
- DDX41 | c.*271G>A | 3'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as rs778864620, COSV57251959; called by mutect2, varscan2
- DIPK1B | chr9:136726810 C>T | 3'Flank (SNP) | VAF 7/38 reads (18%) | catalogued as rs762878594; called by muse, mutect2, varscan2
- ICMT | c.284+437C>T | Intron (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- MAP2K4 | c.393+381C>T | Intron (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- SNORA71E | n.60A>T | RNA (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- SRCAP | c.1135-156A>T | Intron (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
